Somatic mutation profile of tumor specimen C3L-00009-01 (aliquot CPT0001380005) from CPTAC case C3L-00009, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G2; Age at diagnosis: 76.6 years (27,968 days).
Specimen C3L-00009-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 690cb2c5-d8e4-4243-9b4b-651abe97d294.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00009-32 (Blood Derived Normal), aliquot CPT0000100163; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d0759b0d-da63-4941-b981-dfe022e39897

The open-access MAF lists 381 somatic variants for this specimen: 276 protein-altering or splice-affecting, 71 silent, 34 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 246, Silent 71, Nonsense Mutation 12, Intron 12, RNA 7, 5'UTR 6, Frame Shift Del 6, Splice Site 5, 3'UTR 4, 3'Flank 3, Frame Shift Ins 2, 5'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RYR2 | c.14845T>C p.W4949R | Missense Mutation (SNP) | VAF 7/122 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs794728810; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2
- TP53 | c.736A>G p.M246V | Missense Mutation (SNP) | VAF 55/277 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs483352695, CM942294, COSV52664850, COSV52707693, COSV52949209, COSV53107767; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ANKRD30A | c.3136G>T p.E1046* (on ENST00000611781; = p.E990* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 8/105 reads (8%) | catalogued as COSV64623179; called by muse, mutect2
- ANO7 | c.2254C>T p.R752W (on ENST00000274979; = p.R698W on NM_001370694.2) | Missense Mutation (SNP) | VAF 45/362 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs756263486; called by muse, mutect2, varscan2
- ARHGAP30 | c.1129G>A p.E377K | Missense Mutation (SNP) | VAF 12/218 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as COSV63519787; called by muse, mutect2
- ARHGAP32 | c.3757G>T p.E1253* (on ENST00000310343 / NM_001378025.1; = p.E904* on NM_014715.4) | Nonsense Mutation (SNP) | VAF 38/136 reads (28%) | catalogued as COSV59847417; called by muse, mutect2, varscan2
- BFSP2 | c.1030G>A p.G344S | Missense Mutation (SNP) | VAF 40/448 reads (9%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.983); catalogued as rs373262753; called by muse, mutect2
- BTBD16 | c.1201G>T p.G401* | Nonsense Mutation (SNP) | VAF 21/151 reads (14%) | catalogued as COSV53262387; called by muse, mutect2, varscan2
- C16orf78 | c.437G>T p.R146L | Missense Mutation (SNP) | VAF 15/187 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV54555346; called by muse, mutect2
- C4orf54 | c.3856A>G p.M1286V | Missense Mutation (SNP) | VAF 43/239 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs1285539699; called by muse, mutect2, varscan2
- CACYBP | c.70dup p.R24Kfs*4 | Frame Shift Ins (INS) | VAF 14/118 reads (12%) | catalogued as rs1163756426; called by mutect2, pindel
- CCDC40 | c.2762G>T p.R921L | Missense Mutation (SNP) | VAF 150/573 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV66475371; called by muse, mutect2, varscan2
- CDH18 | c.2199C>A p.D733E | Missense Mutation (SNP) | VAF 88/432 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV56951473; called by muse, mutect2, varscan2
- CDH23 | c.4657A>G p.T1553A | Missense Mutation (SNP) | VAF 22/210 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.183); catalogued as rs1347289159; called by muse, mutect2, varscan2
- CDK5 | c.688A>G p.M230V | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs749880275, COSV99876759; called by muse, mutect2, varscan2
- CFAP58 | c.583C>G p.H195D | Missense Mutation (SNP) | VAF 13/257 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV57211333; called by muse, mutect2
- CFHR4 | c.1664C>A p.A555E (on ENST00000367416 / NM_001201551.2; = p.A309E on NM_006684.5) | Missense Mutation (SNP) | VAF 44/298 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.046); catalogued as COSV52225996; called by muse, mutect2, varscan2
- CNTNAP4 | c.1747G>T p.A583S | Missense Mutation (SNP) | VAF 15/182 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.521); catalogued as COSV100273820; called by muse, mutect2
- CNTNAP5 | c.2931C>A p.H977Q | Missense Mutation (SNP) | VAF 28/208 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV70470078; called by muse, varscan2
- CREB3L1 | c.632G>A p.S211N | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1175349225; called by muse, mutect2, varscan2
- CROT | c.832A>T p.M278L | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1206587924; called by muse, mutect2, varscan2
- CYFIP2 | c.864G>C p.K288N | Missense Mutation (SNP) | VAF 7/150 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.076); catalogued as COSV59035359, COSV59047931; called by muse, mutect2
- DAAM2 | c.128C>A p.P43Q | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51301862; called by muse, mutect2
- DNER | c.1663G>C p.G555R | Missense Mutation (SNP) | VAF 19/142 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.974); catalogued as COSV59161849, COSV59168801; called by muse, mutect2, varscan2
- EDN3 | c.10G>T p.G4W | Missense Mutation (SNP) | VAF 55/268 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61107173; called by muse, mutect2, varscan2
- EIF2S3B | c.1064G>T p.G355V | Missense Mutation (SNP) | VAF 60/296 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1285494028; called by muse, mutect2, varscan2
- EIF4B | c.1617A>T p.Q539H | Missense Mutation (SNP) | VAF 23/181 reads (13%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.025); catalogued as COSV50403628; called by muse, mutect2, varscan2
- EPHA5 | c.1709G>T p.S570I | Missense Mutation (SNP) | VAF 21/151 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.03); catalogued as COSV56643525; called by muse, mutect2, varscan2
- ETV2 | c.209T>C p.L70P | Missense Mutation (SNP) | VAF 76/156 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1468429051; called by muse, mutect2, varscan2
- EVPL | c.1790G>A p.R597Q | Missense Mutation (SNP) | VAF 24/266 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs772811795; called by muse, mutect2
- FAAH | c.1009A>G p.M337V | Missense Mutation (SNP) | VAF 77/498 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.024); catalogued as rs1204659876; called by muse, mutect2, varscan2
- FASTKD3 | c.1709T>C p.I570T | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs760255829; called by mutect2, varscan2
- FOLH1 | c.1580G>C p.R527P | Missense Mutation (SNP) | VAF 14/235 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV57048182; called by muse, mutect2
- FPR1 | c.349G>T p.A117S | Missense Mutation (SNP) | VAF 20/348 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.039); catalogued as rs547228145, COSV59053059; called by muse, mutect2
- GPR149 | c.1928C>A p.S643Y | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs752409198; called by muse, mutect2, varscan2
- GRIK2 | c.872C>T p.S291F | Missense Mutation (SNP) | VAF 7/138 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); catalogued as COSV100030152; called by muse, mutect2
- HAUS6 | c.2281A>G p.S761G | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as rs762842123; called by muse, mutect2, varscan2
- IFITM10 | c.23C>A p.P8Q | Missense Mutation (SNP) | VAF 18/246 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as COSV52587764; called by muse, mutect2
- IQCG | c.280G>A p.V94M | Missense Mutation (SNP) | VAF 48/162 reads (30%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs146833269; called by mutect2, varscan2
- KCNH1 | c.2287G>A p.D763N (on ENST00000271751 / NM_172362.3; = p.D736N on NM_002238.4) | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV55105077; called by muse, mutect2, varscan2
- KEAP1 | c.1808G>T p.G603V | Missense Mutation (SNP) | VAF 40/235 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50261740; called by muse, mutect2, varscan2
- KLHL1 | c.1769G>C p.R590P | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748882149, COSV64769060, COSV64786398; called by muse, mutect2, varscan2
- KMT2B | c.7895G>T p.R2632L | Missense Mutation (SNP) | VAF 40/249 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53076014; called by muse, mutect2, varscan2
- LIFR | c.3047T>C p.I1016T | Missense Mutation (SNP) | VAF 66/505 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs373474993; called by muse, mutect2, varscan2
- MAGEB6 | c.684G>T p.E228D | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.08); catalogued as COSV66872675; called by muse, mutect2, varscan2
- MDM1 | c.811A>T p.I271L | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV57447683; called by muse, mutect2, varscan2
- MEX3D | c.682G>T p.G228C | Missense Mutation (SNP) | VAF 61/234 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs192955521, COSV101183462; called by muse, mutect2, varscan2
- MUC4 | c.7349C>G p.P2450R | Missense Mutation (SNP) | VAF 100/990 reads (10%) | SIFT tolerated, low confidence (0.87); PolyPhen possibly damaging (0.811); catalogued as rs200212097; called by muse, varscan2
- MYO5B | c.1304G>A p.G435E | Missense Mutation (SNP) | VAF 57/503 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs578050757; called by muse, mutect2, varscan2
- NCKAP5 | c.2445A>C p.K815N | Missense Mutation (SNP) | VAF 19/187 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.787); catalogued as rs776322123; called by muse, mutect2, varscan2
- NEGR1 | c.770G>T p.W257L | Missense Mutation (SNP) | VAF 44/193 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100163681; called by muse, mutect2, varscan2
- OR2A5 | c.532T>G p.F178V | Missense Mutation (SNP) | VAF 65/440 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV68739043; called by muse, mutect2, varscan2
- OR2T34 | c.749T>C p.M250T | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs1473660056; called by muse, mutect2
- OR52E8 | c.254C>A p.P85H | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs766886654; called by muse, mutect2, varscan2
- OR5I1 | c.290A>T p.Y97F | Missense Mutation (SNP) | VAF 17/165 reads (10%) | SIFT tolerated (0.67); PolyPhen benign (0.022); catalogued as rs1472309083; called by muse, mutect2, varscan2
- OR5M11 | c.109G>T p.V37F | Missense Mutation (SNP) | VAF 19/209 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.024); catalogued as COSV73141953; called by muse, mutect2
- OR5T3 | c.705G>T p.L235F | Missense Mutation (SNP) | VAF 24/196 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.029); catalogued as COSV57382669; called by muse, mutect2, varscan2
- PCDH15 | c.867G>C p.L289F | Missense Mutation (SNP) | VAF 26/372 reads (7%) | SIFT tolerated (0.43); PolyPhen benign (0.062); catalogued as COSV100225812; called by muse, mutect2
- PCDHGB1 | c.2117C>T p.A706V | Missense Mutation (SNP) | VAF 65/315 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.198); catalogued as COSV53919388; called by muse, mutect2, varscan2
- PHLPP2 | c.2140C>T p.Q714* | Nonsense Mutation (SNP) | VAF 20/129 reads (16%) | catalogued as COSV62425320; called by muse, mutect2
- PKHD1 | c.10951C>T p.P3651S | Missense Mutation (SNP) | VAF 30/220 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs1220149658, COSV64393088; called by muse, mutect2, varscan2
- PPP1R9A | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 39/154 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.343); catalogued as COSV56914176; called by muse, mutect2, varscan2
- PXDN | c.2472C>G p.F824L | Missense Mutation (SNP) | VAF 31/666 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53245328; called by muse, mutect2
- RFPL2 | c.406G>T p.D136Y | Missense Mutation (SNP) | VAF 136/438 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.882); catalogued as rs1216393140, COSV50708918; called by muse, mutect2, varscan2
- RIMS1 | c.760C>T p.P254S | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.67); PolyPhen benign (0.015); catalogued as COSV99330272; called by muse, mutect2
- SDC2 | c.127G>A p.V43M | Missense Mutation (SNP) | VAF 19/215 reads (9%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.692); catalogued as rs1309764713; called by muse, mutect2
- SEMA5A | c.1357G>T p.E453* | Nonsense Mutation (SNP) | VAF 96/444 reads (22%) | catalogued as COSV66804610; called by muse, mutect2, varscan2
- SLC18A2 | c.766G>T p.A256S | Missense Mutation (SNP) | VAF 35/286 reads (12%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as COSV104404056; called by muse, mutect2, varscan2
- SLC30A10 | c.1027G>A p.G343R | Missense Mutation (SNP) | VAF 30/274 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs959141901; called by muse, mutect2, varscan2
- SLCO5A1 | c.2308C>T p.R770W | Missense Mutation (SNP) | VAF 48/454 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs544002796, COSV52656995, COSV99481084; called by muse, mutect2
- SNAPC4 | c.2717G>A p.R906H | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as rs1023537386, COSV53731920; called by muse, mutect2, varscan2
- SOX5 | c.1063G>T p.G355W | Missense Mutation (SNP) | VAF 44/228 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as COSV58617423; called by muse, mutect2, varscan2
- SSRP1 | c.1454G>T p.G485V | Missense Mutation (SNP) | VAF 18/285 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1046160960; called by muse, mutect2
- STON2 | c.151G>T p.G51W | Missense Mutation (SNP) | VAF 66/207 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as rs745574107; called by muse, mutect2, varscan2
- STOX2 | c.2585G>T p.R862L | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs1252539753; called by muse, mutect2, varscan2
- STYXL2 | c.456G>T p.K152N | Missense Mutation (SNP) | VAF 49/310 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99068459; called by muse, mutect2, varscan2
- STYXL2 | c.712G>C p.A238P | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54801697, COSV99608439; called by muse, mutect2, varscan2
- SYNM | c.437C>A p.A146E | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT tolerated (0.85); PolyPhen possibly damaging (0.47); catalogued as rs1555482499; called by muse, mutect2
- TBCE | c.1275C>A p.D425E (on ENST00000366601; = p.D488E on NM_003193.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/512 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1227321643; called by muse, mutect2
- TCIM | c.261G>T p.R87S | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV59928442; called by muse, mutect2, varscan2
- TENM1 | c.4146G>T p.L1382F | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV64428284; called by muse, mutect2, varscan2
- TEX37 | c.78G>T p.Q26H | Missense Mutation (SNP) | VAF 33/238 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.548); catalogued as COSV57555467; called by muse, mutect2, varscan2
- THEM4 | c.223C>T p.R75C | Missense Mutation (SNP) | VAF 26/404 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs527741211; called by muse, mutect2
- TNNI1 | c.373C>T p.R125W | Missense Mutation (SNP) | VAF 51/354 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757767988, COSV60189136; called by muse, mutect2, varscan2
- TRIM49C | c.953T>C p.V318A | Missense Mutation (SNP) | VAF 45/236 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1485027442; called by muse, mutect2, varscan2
- TUB | c.811C>T p.R271W (on ENST00000299506 / NM_177972.3; = p.R326W on NM_003320.4) | Missense Mutation (SNP) | VAF 41/494 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766908413, COSV55107758; called by muse, mutect2
- UBASH3B | c.1234G>C p.G412R | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as COSV52495281; called by muse, mutect2, varscan2
- UBXN11 | c.1141G>A p.E381K (on ENST00000374221 / NM_183008.2; = p.E348K on NM_145345.2) | Missense Mutation (SNP) | VAF 47/216 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.018); catalogued as COSV53329543; called by muse, mutect2, varscan2
- VPS13B | c.3031T>C p.Y1011H | Missense Mutation (SNP) | VAF 129/506 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.154); catalogued as rs771021187; called by muse, mutect2, varscan2
- XIRP2 | c.6446G>T p.G2149V (on ENST00000628543; = p.G2324V on NM_152381.6) | Missense Mutation (SNP) | VAF 43/260 reads (17%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs776896507; called by muse, mutect2, varscan2
- YBX3 | c.413G>T p.G138V | Missense Mutation (SNP) | VAF 36/407 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54385424; called by muse, mutect2
- ZFHX4 | c.9038G>T p.G3013V | Missense Mutation (SNP) | VAF 21/241 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV50850555; called by muse, mutect2
- ZFYVE28 | c.1216G>T p.V406L | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.012); catalogued as COSV52108284; called by muse, mutect2, varscan2
- ZKSCAN8 | c.1334A>G p.H445R | Missense Mutation (SNP) | VAF 18/218 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.127); catalogued as rs779396389; called by muse, mutect2
- ZNF415 | c.1307G>A p.G436E | Missense Mutation (SNP) | VAF 26/354 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV54704682; called by muse, mutect2
- ZNF454 | c.338G>T p.R113I | Missense Mutation (SNP) | VAF 13/166 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV100194658; called by muse, mutect2
- ZNF572 | c.1016G>A p.R339H | Missense Mutation (SNP) | VAF 13/153 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.471); catalogued as rs201968418, COSV60002199; called by muse, mutect2
- ZNF804A | c.2450G>T p.G817V | Missense Mutation (SNP) | VAF 27/221 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as COSV100167284; called by mutect2, varscan2
- ZNF835 | c.326C>T p.P109L | Missense Mutation (SNP) | VAF 87/408 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.342); catalogued as rs576625581, COSV73379232; called by muse, mutect2, varscan2
- AASDH | c.1571C>A p.S524Y | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.656); called by muse, mutect2
- ABCB1 | c.2978C>G p.S993* | Nonsense Mutation (SNP) | VAF 141/586 reads (24%) | called by muse, mutect2, varscan2
- ABCB6 | c.888G>T p.K296N | Missense Mutation (SNP) | VAF 38/277 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AC011005.1 | c.626T>A p.L209Q | Missense Mutation (SNP) | VAF 90/428 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ACSBG1 | c.1928C>A p.A643D | Missense Mutation (SNP) | VAF 26/313 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); called by muse, mutect2
- ADAMTS20 | c.5049del p.K1684Nfs*10 | Frame Shift Del (DEL) | VAF 17/127 reads (13%) | called by mutect2, pindel, varscan2
- ADAMTS20 | c.4331G>C p.C1444S | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADD2 | c.101T>A p.L34H | Missense Mutation (SNP) | VAF 32/220 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- ADD3 | c.1234G>A p.A412T | Missense Mutation (SNP) | VAF 17/295 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); called by muse, mutect2
- ADGRV1 | c.12961dup p.E4321Gfs*5 | Frame Shift Ins (INS) | VAF 57/239 reads (24%) | called by mutect2, pindel, varscan2
- ADRA1D | c.334del p.A112Qfs*25 | Frame Shift Del (DEL) | VAF 56/275 reads (20%) | called by mutect2, pindel, varscan2
- AGXT | c.961G>T p.V321F | Missense Mutation (SNP) | VAF 32/254 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- ANK3 | c.118G>T p.D40Y | Missense Mutation (SNP) | VAF 22/168 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ANKDD1B | c.751G>A p.V251M | Missense Mutation (SNP) | VAF 39/174 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- ANKS1B | c.2870G>T p.R957L (on ENST00000547776 / NM_152788.4; = p.R183L on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 65/325 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ATN1 | c.565G>T p.V189L | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ATP2B2 | c.937G>T p.A313S (on ENST00000352432; = p.A324S on NM_001001331.4) | Missense Mutation (SNP) | VAF 54/304 reads (18%) | SIFT tolerated (0.67); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- BACH1 | c.235G>T p.V79L | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, varscan2
- BAG3 | c.1496T>G p.I499S | Missense Mutation (SNP) | VAF 54/531 reads (10%) | SIFT tolerated (0.65); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- BNC1 | c.1808C>A p.P603H | Missense Mutation (SNP) | VAF 61/308 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- CA8 | c.727T>G p.S243A | Missense Mutation (SNP) | VAF 34/450 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.536); called by muse, mutect2
- CALCR | c.433G>T p.A145S | Missense Mutation (SNP) | VAF 31/131 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- CAMTA1 | c.3980A>T p.Y1327F | Missense Mutation (SNP) | VAF 21/271 reads (8%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.001); called by muse, mutect2
- CCDC152 | c.317C>A p.S106Y | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CCDC54 | c.652A>C p.K218Q | Missense Mutation (SNP) | VAF 10/206 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.758); called by muse, mutect2
- CCT8L2 | c.1628A>G p.H543R | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); called by muse, mutect2
- CDK5RAP1 | c.1304-8_1316del p.X435_splice (on ENST00000357886 / NM_001365728.1; = p.X421_splice on NM_016082.4 and 2 other RefSeq transcripts) | Splice Site (DEL) | VAF 8/124 reads (6%) | called by mutect2, pindel
- CERS3 | c.83A>T p.H28L | Missense Mutation (SNP) | VAF 43/251 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- CFAP92 | c.571C>T p.L191F | Missense Mutation (SNP) | VAF 35/250 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- COL22A1 | c.3742G>T p.D1248Y | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); called by muse, mutect2
- CSF3R | c.2165C>A p.T722N | Missense Mutation (SNP) | VAF 20/266 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.383); called by muse, mutect2
- CSMD1 | c.9931G>T p.G3311W (on ENST00000520002; = p.G3310W on NM_033225.6) | Missense Mutation (SNP) | VAF 22/183 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CUX1 | c.3260G>T p.S1087I | Missense Mutation (SNP) | VAF 18/304 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.068); called by muse, mutect2
- CYFIP2 | c.1553G>T p.C518F | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.9); called by muse, mutect2
- DAPK1 | c.2276G>T p.R759M | Missense Mutation (SNP) | VAF 36/174 reads (21%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.541); called by muse, varscan2
- DAZL | c.3+1G>T p.X1_splice | Splice Site (SNP) | VAF 61/354 reads (17%) | called by muse, mutect2, varscan2
- DAZL | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 56/347 reads (16%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DCC | c.4325T>A p.I1442N | Missense Mutation (SNP) | VAF 67/466 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DENND5A | c.833A>T p.E278V | Missense Mutation (SNP) | VAF 39/321 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DGKB | c.427T>C p.S143P | Missense Mutation (SNP) | VAF 8/190 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DNAH1 | c.2006G>T p.G669V | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- DNAH2 | c.9335A>G p.E3112G | Missense Mutation (SNP) | VAF 34/168 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DOCK10 | c.871A>G p.I291V | Missense Mutation (SNP) | VAF 35/196 reads (18%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- EIF4G1 | c.2274+1G>T p.X758_splice (on ENST00000346169 / NM_198241.3; = p.X563_splice on NM_004953.5) | Splice Site (SNP) | VAF 102/425 reads (24%) | called by muse, mutect2, varscan2
- EMC2 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 8/175 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); called by muse, mutect2
- ETAA1 | c.925A>C p.S309R | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EXO1 | c.1939A>C p.N647H | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- FAM135B | c.3943C>A p.Q1315K | Missense Mutation (SNP) | VAF 69/333 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- FAT3 | c.8311C>A p.L2771I | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.662); called by muse, mutect2, varscan2
- FMN2 | c.366C>G p.S122R | Missense Mutation (SNP) | VAF 26/216 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- FMN2 | c.2438C>A p.P813H | Missense Mutation (SNP) | VAF 26/186 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- FRMPD1 | c.449C>A p.A150D | Missense Mutation (SNP) | VAF 28/233 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- FRY | c.4544C>A p.P1515H | Missense Mutation (SNP) | VAF 11/186 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FSIP2 | c.15439G>C p.D5147H | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- GABRR3 | c.1252G>T p.D418Y | Missense Mutation (SNP) | VAF 31/364 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); called by muse, mutect2
- GALNT17 | c.1039A>T p.M347L | Missense Mutation (SNP) | VAF 45/214 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- GK2 | c.415T>C p.S139P | Missense Mutation (SNP) | VAF 50/196 reads (26%) | SIFT tolerated (0.95); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GPC3 | c.1583A>G p.Y528C | Missense Mutation (SNP) | VAF 60/191 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GPR173 | c.511G>T p.E171* | Nonsense Mutation (SNP) | VAF 24/123 reads (20%) | called by muse, mutect2, varscan2
- GYS2 | c.133T>C p.Y45H | Missense Mutation (SNP) | VAF 72/385 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.012); called by muse, varscan2
- HACD1 | c.52G>T p.G18C | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- ICAM1 | c.194C>A p.P65H | Missense Mutation (SNP) | VAF 20/456 reads (4%) | SIFT tolerated (0.58); PolyPhen benign (0.043); called by muse, mutect2
- INHBA | c.539A>G p.K180R | Missense Mutation (SNP) | VAF 19/321 reads (6%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2
- IQCG | c.1198-2A>G p.X400_splice | Splice Site (SNP) | VAF 41/166 reads (25%) | called by muse, mutect2, varscan2
- ITIH5 | c.2752del p.E918Sfs*15 | Frame Shift Del (DEL) | VAF 44/355 reads (12%) | called by mutect2, varscan2
- ITSN1 | c.4438G>T p.G1480C | Missense Mutation (SNP) | VAF 40/325 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITSN1 | c.4439G>T p.G1480V | Missense Mutation (SNP) | VAF 39/325 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITSN2 | c.4922A>T p.Q1641L | Missense Mutation (SNP) | VAF 29/220 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- IZUMO3 | c.154G>C p.E52Q | Missense Mutation (SNP) | VAF 20/303 reads (7%) | SIFT tolerated (0.31); called by muse, mutect2
- JAKMIP1 | c.2224C>T p.P742S | Missense Mutation (SNP) | VAF 13/197 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.005); called by muse, mutect2
- KIF26B | c.434G>T p.R145M | Missense Mutation (SNP) | VAF 46/256 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- KLF12 | c.494A>G p.H165R | Missense Mutation (SNP) | VAF 20/155 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- KRT31 | c.8A>G p.Y3C | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- KRTAP8-1 | c.143G>T p.G48V | Missense Mutation (SNP) | VAF 22/209 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LILRB2 | c.1315C>G p.P439A | Missense Mutation (SNP) | VAF 24/183 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- LINC02740 | n.95A>T | Splice Region (SNP) | VAF 11/157 reads (7%) | called by muse, mutect2
- LPAR1 | c.673T>C p.Y225H | Missense Mutation (SNP) | VAF 48/245 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRP1B | c.10312C>A p.P3438T | Missense Mutation (SNP) | VAF 34/181 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRRK2 | c.7548A>T p.E2516D | Missense Mutation (SNP) | VAF 41/181 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); called by muse, varscan2
- MAD2L2 | c.559A>G p.I187V | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.59); PolyPhen benign (0.003); called by mutect2, varscan2
- MARK1 | c.1031T>G p.F344C | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- MARK1 | c.1262G>T p.R421L | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- MCCD1 | c.149G>A p.G50E | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, mutect2
- MEGF6 | c.3072G>C p.W1024C | Missense Mutation (SNP) | VAF 35/265 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- MPEG1 | c.1278C>G p.H426Q | Missense Mutation (SNP) | VAF 56/237 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- MPHOSPH9 | c.962del p.G321Efs*44 | Frame Shift Del (DEL) | VAF 33/223 reads (15%) | called by mutect2, pindel, varscan2
- MPPE1 | c.1118T>A p.L373H | Missense Mutation (SNP) | VAF 16/237 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- MXI1 | c.217G>T p.V73L | Missense Mutation (SNP) | VAF 34/436 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.288); called by muse, mutect2
- MYLK | c.3703+5T>C | Splice Region (SNP) | VAF 31/327 reads (9%) | called by muse, mutect2
- NALCN | c.1718C>A p.P573H | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NAV1 | c.3320A>G p.N1107S | Missense Mutation (SNP) | VAF 13/222 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); called by muse, mutect2
- NDUFS1 | c.1735A>T p.I579L | Missense Mutation (SNP) | VAF 49/397 reads (12%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- NEGR1 | c.769T>A p.W257R | Missense Mutation (SNP) | VAF 44/192 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NFAM1 | c.430G>T p.G144C | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- NLGN1 | c.1178T>A p.L393* | Nonsense Mutation (SNP) | VAF 34/161 reads (21%) | called by muse, mutect2, varscan2
- NMT2 | c.122_133del p.G41_G44del | In Frame Del (DEL) | VAF 26/139 reads (19%) | called by mutect2, pindel, varscan2
- NOL4 | c.544A>G p.T182A | Missense Mutation (SNP) | VAF 24/187 reads (13%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- NR5A2 | c.136G>C p.E46Q | Missense Mutation (SNP) | VAF 26/355 reads (7%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.031); called by muse, mutect2
- NRCAM | c.1169C>A p.P390H (on ENST00000379028 / NM_001371124.1; = p.P384H on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/155 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OGDHL | c.551C>A p.S184Y | Missense Mutation (SNP) | VAF 46/320 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.139); called by muse, varscan2
- OPN4 | c.610C>G p.P204A | Missense Mutation (SNP) | VAF 45/265 reads (17%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- OR10J1 | c.278C>G p.S93* | Nonsense Mutation (SNP) | VAF 29/237 reads (12%) | called by muse, mutect2, varscan2
- OR2M7 | c.608G>T p.C203F | Missense Mutation (SNP) | VAF 64/376 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR5B2 | c.782G>T p.S261I | Missense Mutation (SNP) | VAF 40/269 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- OTOGL | c.1442-5_1444delinsTTTTTTTT p.X481_splice (on ENST00000547103; = p.X472_splice on NM_173591.4 and 2 other RefSeq transcripts) | Splice Site (ONP) | VAF 4/38 reads (11%) | called by muse*, pindel, varscan2*
- PAGE5 | c.358A>G p.T120A | Missense Mutation (SNP) | VAF 40/148 reads (27%) | SIFT tolerated (0.59); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PAX1 | c.1214G>T p.G405V | Missense Mutation (SNP) | VAF 26/131 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.941); called by muse, mutect2
- PBRM1 | c.499C>T p.Q167* | Nonsense Mutation (SNP) | VAF 43/190 reads (23%) | called by muse, mutect2, varscan2
- PCDHB6 | c.941A>G p.D314G | Missense Mutation (SNP) | VAF 50/246 reads (20%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- PDE4D | c.364G>T p.D122Y | Missense Mutation (SNP) | VAF 18/380 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.819); called by muse, mutect2
- PI4KB | c.1045A>T p.T349S (on ENST00000368873 / NM_001369623.1; = p.T361S on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/495 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.235); called by muse, mutect2
- PIM3 | c.136C>G p.L46V | Missense Mutation (SNP) | VAF 35/169 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.098); called by muse, mutect2
- PKHD1L1 | c.2753G>T p.G918V | Missense Mutation (SNP) | VAF 29/144 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- PLA2G15 | c.11A>T p.H4L | Missense Mutation (SNP) | VAF 19/170 reads (11%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLA2R1 | c.3997C>G p.P1333A | Missense Mutation (SNP) | VAF 29/155 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.103); called by muse, varscan2
- PLCD3 | c.875C>T p.A292V | Missense Mutation (SNP) | VAF 28/185 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLEKHB2 | c.669G>T p.*223Yext*11 (on ENST00000409279; = p.*222Yext*11 on NM_017958.2 and 2 other RefSeq transcripts) | Nonstop Mutation (SNP) | VAF 6/84 reads (7%) | called by muse, mutect2
- POU3F2 | c.638A>T p.H213L | Missense Mutation (SNP) | VAF 39/267 reads (15%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- PPP1R21 | c.2131G>C p.E711Q (on ENST00000294952 / NM_001135629.3; = p.E700Q on NM_152994.5) | Missense Mutation (SNP) | VAF 23/142 reads (16%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- PTPRF | c.2068G>T p.V690L | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- PXDNL | c.2192A>G p.D731G | Missense Mutation (SNP) | VAF 25/189 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RAF1 | c.698C>G p.S233C | Missense Mutation (SNP) | VAF 63/335 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- REG1B | c.141C>G p.C47W | Missense Mutation (SNP) | VAF 45/333 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RNF135 | c.647C>T p.T216I | Missense Mutation (SNP) | VAF 89/560 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RP1 | c.5468A>T p.H1823L | Missense Mutation (SNP) | VAF 24/373 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2
- RXRG | c.1368G>T p.L456F | Missense Mutation (SNP) | VAF 38/179 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, varscan2
- RYR2 | c.12108C>A p.D4036E | Missense Mutation (SNP) | VAF 52/377 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- SCN7A | c.2464G>T p.E822* | Nonsense Mutation (SNP) | VAF 33/329 reads (10%) | called by muse, mutect2, varscan2
- SERPINC1 | c.979G>C p.V327L | Missense Mutation (SNP) | VAF 37/257 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- SFMBT2 | c.770C>T p.S257L | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT tolerated (0.43); PolyPhen benign (0.024); called by muse, mutect2
- SHMT2 | c.323G>T p.G108V | Missense Mutation (SNP) | VAF 20/394 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC17A6 | c.499A>G p.M167V | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- SLC35F1 | c.211T>A p.S71T | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- SLC7A4 | c.12del p.L5Cfs*14 | Frame Shift Del (DEL) | VAF 8/21 reads (38%) | called by mutect2, pindel, varscan2
- SLC7A9 | c.803T>A p.I268N | Missense Mutation (SNP) | VAF 35/614 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); called by muse, mutect2
- SMARCA1 | c.2273C>A p.A758E | Missense Mutation (SNP) | VAF 40/159 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- SMARCAD1 | c.79C>A p.P27T | Missense Mutation (SNP) | VAF 62/337 reads (18%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- SPATA16 | c.821G>A p.C274Y | Missense Mutation (SNP) | VAF 47/413 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.325); called by muse, mutect2, varscan2
- STK11IP | c.630G>C p.E210D | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SUCO | c.2954A>G p.Q985R | Missense Mutation (SNP) | VAF 45/207 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SYNE2 | c.7666T>C p.Y2556H | Missense Mutation (SNP) | VAF 45/201 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SYT10 | c.1375G>C p.G459R | Missense Mutation (SNP) | VAF 28/194 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TCTN2 | c.1778C>T p.S593L | Missense Mutation (SNP) | VAF 20/482 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.02); called by muse, mutect2
- TCTN2 | c.1913C>T p.T638I | Missense Mutation (SNP) | VAF 40/351 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- TENM1 | c.1511C>A p.P504H | Missense Mutation (SNP) | VAF 40/139 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TENM3 | c.143A>T p.K48I | Missense Mutation (SNP) | VAF 40/532 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.761); called by muse, mutect2
- TEX13C | c.1849C>A p.P617T | Missense Mutation (SNP) | VAF 36/334 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.237); called by muse, varscan2
- TIGD2 | c.265C>T p.Q89* | Nonsense Mutation (SNP) | VAF 44/246 reads (18%) | called by muse, mutect2, varscan2
- TMED2 | c.56C>T p.S19L | Missense Mutation (SNP) | VAF 23/187 reads (12%) | SIFT tolerated (0.53); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- TMEM132D | c.2936A>T p.N979I | Missense Mutation (SNP) | VAF 22/214 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.316); called by muse, mutect2
- TMEM151B | c.311A>G p.H104R | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- TMEM185B | c.373G>T p.V125L | Missense Mutation (SNP) | VAF 50/287 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- TMEM220 | c.140T>A p.V47D | Missense Mutation (SNP) | VAF 38/214 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- TMEM236 | c.510A>T p.Q170H | Missense Mutation (SNP) | VAF 85/621 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.717); called by muse, mutect2, varscan2
- TMTC1 | c.648G>T p.M216I (on ENST00000539277 / NM_001193451.2; = p.M108I on NM_175861.3) | Missense Mutation (SNP) | VAF 48/273 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- TRPC6 | c.1925T>C p.I642T | Missense Mutation (SNP) | VAF 26/234 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- UBASH3A | c.90del p.M31Wfs*9 | Frame Shift Del (DEL) | VAF 15/91 reads (16%) | called by mutect2, pindel, varscan2
- UBR2 | c.1468A>T p.T490S | Missense Mutation (SNP) | VAF 11/141 reads (8%) | SIFT tolerated (0.48); PolyPhen benign (0.001); called by muse, mutect2
- UNC80 | c.4623G>C p.K1541N | Missense Mutation (SNP) | VAF 24/195 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- USH2A | c.13795C>A p.L4599M | Missense Mutation (SNP) | VAF 10/300 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- USH2A | c.12119G>T p.R4040L | Missense Mutation (SNP) | VAF 41/205 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- USH2A | c.6241G>C p.A2081P | Missense Mutation (SNP) | VAF 22/317 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.029); called by muse, mutect2
- VPS41 | c.2350C>T p.L784F | Missense Mutation (SNP) | VAF 8/240 reads (3%) | SIFT tolerated (0.71); PolyPhen benign (0.272); called by muse, mutect2
- WDCP | c.1799A>G p.Y600C | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- WDFY4 | c.4796T>A p.L1599Q | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- WWOX | c.1085G>C p.C362S | Missense Mutation (SNP) | VAF 65/444 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.743); called by muse, mutect2, varscan2
- ZC3H6 | c.2797G>A p.A933T | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- ZNF229 | c.1342C>A p.L448M | Missense Mutation (SNP) | VAF 33/171 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF236 | c.1856C>T p.P619L | Missense Mutation (SNP) | VAF 22/159 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF385B | c.676T>A p.S226T | Missense Mutation (SNP) | VAF 37/250 reads (15%) | SIFT tolerated (0.64); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ZNF518B | c.1262T>C p.F421S | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.014); called by muse, mutect2
- ZNF543 | c.1367G>C p.C456S | Missense Mutation (SNP) | VAF 11/278 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZNF594 | c.766A>T p.I256L | Missense Mutation (SNP) | VAF 32/173 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- ZNF716 | c.442T>C p.C148R | Missense Mutation (SNP) | VAF 10/222 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); called by muse, mutect2
- ZNF836 | c.883A>T p.S295C | Missense Mutation (SNP) | VAF 93/235 reads (40%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZSCAN4 | c.1146C>A p.N382K | Missense Mutation (SNP) | VAF 51/175 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ZSCAN9 | c.798C>A p.S266R | Missense Mutation (SNP) | VAF 21/317 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.039); called by muse, mutect2
- ACP4 | c.1044C>T p.L348= | Silent (SNP) | VAF 7/101 reads (7%) | catalogued as COSV54516501, COSV54519369; called by muse, mutect2
- ADORA3 | c.222G>A p.L74= | Silent (SNP) | VAF 65/428 reads (15%) | catalogued as rs1410524776; called by muse, mutect2, varscan2
- ANKRD17 | c.7272A>G p.P2424= | Silent (SNP) | VAF 144/398 reads (36%) | catalogued as rs767724836; called by muse, mutect2, varscan2
- AP4B1 | c.559C>T p.L187= | Silent (SNP) | VAF 71/324 reads (22%) | called by muse, mutect2, varscan2
- ARHGEF11 | c.2181G>C p.G727= | Silent (SNP) | VAF 16/164 reads (10%) | called by muse, mutect2
- BTNL8 | c.1323G>A p.R441= | Silent (SNP) | VAF 106/545 reads (19%) | catalogued as rs375532895; called by muse, mutect2, varscan2
- C1QB | c.660C>A p.V220= | Silent (SNP) | VAF 15/98 reads (15%) | catalogued as rs548014292; called by muse, mutect2, varscan2
- CCL3L3 | c.201C>T p.T67= | Silent (SNP) | VAF 82/604 reads (14%) | called by muse, mutect2, varscan2
- CDK15 | c.30A>G p.V10= | Silent (SNP) | VAF 14/127 reads (11%) | catalogued as rs551306481; called by muse, mutect2, varscan2
- CELF4 | c.822C>A p.A274= | Silent (SNP) | VAF 12/107 reads (11%) | called by muse, mutect2, varscan2
- CHST1 | c.972G>T p.L324= | Silent (SNP) | VAF 28/235 reads (12%) | called by muse, mutect2, varscan2
- CLSTN1 | c.2406C>T p.I802= (on ENST00000377298 / NM_001009566.3; = p.I792= on NM_014944.4) | Silent (SNP) | VAF 15/221 reads (7%) | called by muse, mutect2
- COL6A3 | c.3588C>T p.T1196= | Silent (SNP) | VAF 44/290 reads (15%) | catalogued as rs1434102843; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COMMD5 | c.561A>G p.A187= | Silent (SNP) | VAF 22/417 reads (5%) | called by muse, mutect2
- CROCC | c.132C>T p.I44= | Silent (SNP) | VAF 21/117 reads (18%) | called by muse, mutect2, varscan2
- CYP3A7 | c.1035C>T p.P345= | Silent (SNP) | VAF 20/363 reads (6%) | called by muse, mutect2
- DNAAF4 | c.1032T>C p.I344= | Silent (SNP) | VAF 19/77 reads (25%) | called by muse, mutect2, varscan2
- DNAH14 | c.151C>T p.L51= | Silent (SNP) | VAF 14/222 reads (6%) | called by muse, mutect2
- EPB41L2 | c.570A>T p.A190= | Silent (SNP) | VAF 37/398 reads (9%) | called by muse, mutect2
- ERICH3 | c.2898A>G p.R966= | Silent (SNP) | VAF 32/299 reads (11%) | called by muse, mutect2, varscan2
- FBN2 | c.5469G>T p.V1823= | Silent (SNP) | VAF 70/356 reads (20%) | called by muse, mutect2, varscan2
- FRMPD1 | c.450C>A p.A150= | Silent (SNP) | VAF 29/236 reads (12%) | called by muse, mutect2, varscan2
- FTMT | c.636G>T p.V212= | Silent (SNP) | VAF 47/272 reads (17%) | catalogued as COSV58421303; called by muse, mutect2, varscan2
- FYB1 | c.1620C>T p.I540= | Silent (SNP) | VAF 36/216 reads (17%) | catalogued as COSV100685019; called by muse, varscan2
- FZD5 | c.990C>T p.S330= | Silent (SNP) | VAF 49/346 reads (14%) | called by muse, mutect2, varscan2
- HDC | c.753T>C p.C251= | Silent (SNP) | VAF 75/388 reads (19%) | called by muse, mutect2, varscan2
- HTR3D | c.87C>T p.I29= | Silent (SNP) | VAF 60/310 reads (19%) | called by muse, mutect2, varscan2
- IGHV2-26 | c.189G>T p.G63= | Silent (SNP) | VAF 47/336 reads (14%) | catalogued as rs782146717; called by muse, mutect2, varscan2
- ITGB4 | c.4590G>T p.T1530= | Silent (SNP) | VAF 66/577 reads (11%) | catalogued as COSV104387377; called by muse, mutect2, varscan2
- KMT2C | c.3333T>C p.H1111= | Silent (SNP) | VAF 39/146 reads (27%) | called by muse, mutect2, varscan2
- LCMT1 | c.51G>A p.S17= | Silent (SNP) | VAF 11/248 reads (4%) | catalogued as COSV66724766; called by muse, mutect2
- LILRB5 | c.1728G>A p.R576= (on ENST00000449561 / NM_001081442.3; = p.R575= on NM_006840.5) | Silent (SNP) | VAF 194/345 reads (56%) | called by muse, mutect2, varscan2
- LPXN | c.156C>T p.N52= | Silent (SNP) | VAF 6/110 reads (5%) | called by muse, mutect2
- MACF1 | c.5535G>A p.V1845= | Silent (SNP) | VAF 21/190 reads (11%) | called by muse, mutect2, varscan2
- MDGA2 | c.1437G>A p.T479= (on ENST00000399232 / NM_001113498.2; = p.T181= on NM_182830.4) | Silent (SNP) | VAF 54/221 reads (24%) | catalogued as rs776675809, COSV100638842, COSV62096103; called by muse, mutect2, varscan2
- MPPE1 | c.1119C>T p.L373= | Silent (SNP) | VAF 16/236 reads (7%) | catalogued as rs765785638; called by muse, mutect2
- MYH7 | c.1194G>T p.G398= | Silent (SNP) | VAF 109/392 reads (28%) | catalogued as COSV62520113; called by muse, mutect2, varscan2
- NEUROD6 | c.429C>A p.I143= | Silent (SNP) | VAF 67/315 reads (21%) | called by muse, mutect2, varscan2
- NPY5R | c.729C>A p.S243= | Silent (SNP) | VAF 48/140 reads (34%) | called by muse, mutect2, varscan2
- NTRK3 | c.1650A>G p.G550= | Silent (SNP) | VAF 48/578 reads (8%) | called by muse, mutect2
- NUMB | c.879A>G p.Q293= (on ENST00000355058; = p.Q282= on NM_003744.5) | Silent (SNP) | VAF 67/352 reads (19%) | catalogued as rs768519638; called by muse, mutect2, varscan2
- OAF | c.96G>T p.L32= | Silent (SNP) | VAF 25/122 reads (20%) | called by muse, mutect2, varscan2
- OLFML2B | c.312C>A p.T104= | Silent (SNP) | VAF 48/522 reads (9%) | called by muse, mutect2
- OR13C9 | c.756T>C p.Y252= | Silent (SNP) | VAF 14/85 reads (16%) | called by muse, mutect2, varscan2
- OR2AG1 | c.480C>G p.T160= | Silent (SNP) | VAF 23/250 reads (9%) | catalogued as COSV56625836; called by muse, mutect2
- OR2J1 | c.354G>T p.V118= | Silent (SNP) | VAF 37/239 reads (15%) | called by muse, mutect2, varscan2
- PATJ | c.4629C>T p.G1543= | Silent (SNP) | VAF 21/197 reads (11%) | catalogued as rs1217184313; called by muse, mutect2, varscan2
- PLCE1 | c.348C>G p.G116= | Silent (SNP) | VAF 84/549 reads (15%) | called by muse, mutect2, varscan2
- POM121L12 | c.648C>T p.A216= | Silent (SNP) | VAF 35/160 reads (22%) | called by muse, mutect2, varscan2
- PPP1R14C | c.285G>C p.L95= | Silent (SNP) | VAF 20/290 reads (7%) | called by muse, mutect2
- PTPRD | c.2973T>C p.D991= | Silent (SNP) | VAF 34/203 reads (17%) | catalogued as rs763952043; called by muse, mutect2, varscan2
- PTPRT | c.2262C>A p.L754= | Silent (SNP) | VAF 21/139 reads (15%) | called by muse, mutect2, varscan2
- RIMS1 | c.1518C>G p.S506= | Silent (SNP) | VAF 61/651 reads (9%) | called by muse, mutect2
- SIMC1 | c.453C>T p.L151= (on ENST00000443967 / NM_001308196.1; = p.L170= on NM_001308195.2) | Silent (SNP) | VAF 16/248 reads (6%) | catalogued as rs1395545905; called by muse, mutect2
- SLC6A19 | c.36C>T p.D12= | Silent (SNP) | VAF 107/471 reads (23%) | catalogued as rs377331317; called by muse, mutect2, varscan2
- SLIT1 | c.1116C>T p.L372= | Silent (SNP) | VAF 15/174 reads (9%) | catalogued as COSV56588109; called by muse, mutect2
- SMNDC1 | c.348G>T p.V116= | Silent (SNP) | VAF 20/221 reads (9%) | called by muse, mutect2
- SNX14 | c.2250T>C p.T750= (on ENST00000314673 / NM_001350535.1; = p.T697= on NM_020468.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 17/107 reads (16%) | called by muse, mutect2, varscan2
- THBS2 | c.288C>T p.S96= | Silent (SNP) | VAF 26/160 reads (16%) | called by muse, mutect2, varscan2
- TMEM255B | c.570G>A p.L190= | Silent (SNP) | VAF 16/152 reads (11%) | catalogued as COSV64704458; called by muse, mutect2
- TMEM255B | c.657C>A p.A219= | Silent (SNP) | VAF 12/83 reads (14%) | called by muse, mutect2, varscan2
- TPH2 | c.1335A>G p.V445= | Silent (SNP) | VAF 29/298 reads (10%) | called by muse, mutect2
- TPO | c.1887T>A p.P629= | Silent (SNP) | VAF 44/582 reads (8%) | called by muse, mutect2
- TPTE2 | c.987T>C p.T329= (on ENST00000400230 / NM_199254.2; = p.T252= on NM_130785.3) | Silent (SNP) | VAF 22/164 reads (13%) | catalogued as rs1304825301; called by muse, mutect2, varscan2
- TRIM17 | c.588G>C p.L196= | Silent (SNP) | VAF 13/160 reads (8%) | called by muse, mutect2
- USH2A | c.8745A>G p.E2915= | Silent (SNP) | VAF 50/352 reads (14%) | called by muse, mutect2, varscan2
- WSCD2 | c.1542G>A p.K514= | Silent (SNP) | VAF 44/332 reads (13%) | catalogued as rs570792620; called by muse, mutect2, varscan2
- XYLT1 | c.1020G>C p.R340= | Silent (SNP) | VAF 18/240 reads (8%) | called by muse, mutect2
- ZDBF2 | c.4455C>T p.V1485= | Silent (SNP) | VAF 10/196 reads (5%) | called by muse, mutect2
- ZFHX3 | c.8025A>C p.A2675= | Silent (SNP) | VAF 35/219 reads (16%) | called by muse, mutect2, varscan2
- ZNF407 | c.4983C>G p.P1661= | Silent (SNP) | VAF 9/160 reads (6%) | called by muse, mutect2
- AC024940.1 | n.261G>C | RNA (SNP) | VAF 16/124 reads (13%) | called by muse, mutect2, varscan2
- AC136759.1 | n.1448C>A | RNA (SNP) | VAF 51/476 reads (11%) | called by muse, mutect2, varscan2
- ADGRA1 | c.4-3819C>T | Intron (SNP) | VAF 46/506 reads (9%) | catalogued as COSV101192778; called by muse, mutect2
- ADGRE4P | n.1403C>G | RNA (SNP) | VAF 18/108 reads (17%) | called by muse, varscan2
- ADGRL2 | c.-39C>A | 5'UTR (SNP) | VAF 7/54 reads (13%) | catalogued as COSV54656936; called by muse, mutect2, varscan2
- ATP2B2 | c.*147C>G | 3'UTR (SNP) | VAF 35/238 reads (15%) | called by muse, mutect2, varscan2
- CPNE2 | c.927+973C>G | Intron (SNP) | VAF 3/41 reads (7%) | called by muse, mutect2
- FAM86DP | n.1029A>T | RNA (SNP) | VAF 53/356 reads (15%) | called by muse, mutect2, varscan2
- HERC2P3 | n.165C>A | RNA (SNP) | VAF 49/398 reads (12%) | called by mutect2, varscan2
- HLA-DQA1 | c.*4C>A | 3'UTR (SNP) | VAF 52/348 reads (15%) | called by muse, varscan2
- IMPDH2 | chr3:49029453 del GC | 5'Flank (DEL) | VAF 26/175 reads (15%) | called by pindel, varscan2
- KLHL14 | c.-43-343C>T | Intron (SNP) | VAF 17/197 reads (9%) | called by muse, mutect2
- LINC00632 | n.95G>T | RNA (SNP) | VAF 8/47 reads (17%) | called by muse, mutect2, varscan2
- MATK | c.*46G>T | 3'UTR (SNP) | VAF 12/141 reads (9%) | called by muse, mutect2
- MBNL1 | c.-1071A>G | 5'UTR (SNP) | VAF 17/200 reads (9%) | catalogued as rs1375283241; called by muse, mutect2
- MBP | c.682-159T>C | Intron (SNP) | VAF 11/191 reads (6%) | catalogued as rs982205637; called by muse, mutect2
- MCM2 | c.-15G>A | 5'UTR (SNP) | VAF 24/305 reads (8%) | catalogued as rs1413317782; called by muse, mutect2
- MEMO1 | c.62-19838C>G | Intron (SNP) | VAF 5/80 reads (6%) | called by muse, mutect2
- MLIP | c.613-11913G>T | Intron (SNP) | VAF 16/238 reads (7%) | called by muse, mutect2
- MYH8 | c.-23C>A | 5'UTR (SNP) | VAF 61/270 reads (23%) | catalogued as rs111802153; called by muse, mutect2, varscan2
- NCAM1 | c.1826-2772C>A | Intron (SNP) | VAF 10/122 reads (8%) | called by muse, mutect2
- NHSL2 | c.-249C>T | 5'UTR (SNP) | VAF 20/88 reads (23%) | called by muse, mutect2, varscan2
- OR7E5P | n.338T>C | RNA (SNP) | VAF 18/210 reads (9%) | called by muse, mutect2
- PLA2G6 | c.210-2828G>A | Intron (SNP) | VAF 33/170 reads (19%) | called by muse, mutect2, varscan2
- PPY | chr17:43938667 A>G | 3'Flank (SNP) | VAF 8/128 reads (6%) | called by muse, mutect2
- PREX2 | c.2716-2898G>T | Intron (SNP) | VAF 31/290 reads (11%) | catalogued as COSV55801043; called by muse, mutect2, varscan2
- RN7SL495P | chr15:22611752 C>T | 5'Flank (SNP) | VAF 14/112 reads (13%) | catalogued as rs745444296; called by mutect2, varscan2
- RPS27A | c.-17-49C>G | Intron (SNP) | VAF 49/266 reads (18%) | called by muse, mutect2, varscan2
- SPG7 | c.861+45G>A | Intron (SNP) | VAF 55/318 reads (17%) | called by muse, mutect2, varscan2
- SYT14 | chr1:210162752 C>A | 3'Flank (SNP) | VAF 14/75 reads (19%) | called by muse, mutect2, varscan2
- TEX35 | chr1:178523302 G>T | 3'Flank (SNP) | VAF 12/82 reads (15%) | catalogued as rs764820576; called by muse, mutect2, varscan2
- TIMM8A | c.-28T>A | 5'UTR (SNP) | VAF 52/183 reads (28%) | called by muse, mutect2, varscan2
- TMEM252 | c.*70C>A | 3'UTR (SNP) | VAF 6/91 reads (7%) | catalogued as COSV101051155; called by muse, mutect2
- TMEM86B | c.52-42G>T | Intron (SNP) | VAF 19/196 reads (10%) | catalogued as rs930119566; called by muse, mutect2
